Somatic mutation profile of tumor specimen TARGET-50-PAJNLT-01A (aliquot TARGET-50-PAJNLT-01A-01D) from TARGET case TARGET-50-PAJNLT, project TARGET-WT (High-Risk Wilms Tumor). Sex at birth: female; Vital status: Dead; Primary diagnosis: Wilms tumor; Tissue or organ of origin: Kidney, NOS; Age at diagnosis: 4.2 years (1,546 days).
Specimen TARGET-50-PAJNLT-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 695eefef-9fda-4bd8-b56a-26eed303bd35.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-50-PAJNLT-10A (Blood Derived Normal), aliquot TARGET-50-PAJNLT-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f603d10a-6d13-48d2-a49d-312a17957bce

The open-access MAF lists 10 somatic variants for this specimen: 7 protein-altering or splice-affecting, 3 silent.
By variant classification: Missense Mutation 5, Silent 3, Splice Site 1, In Frame Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- APOBEC3H | c.526C>T p.R176W | Missense Mutation (SNP) | VAF 8/73 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62379253; called by muse, mutect2, varscan2
- KIF1A | c.3162+1G>A p.X1054_splice | Splice Site (SNP) | VAF 96/204 reads (47%) | catalogued as rs113158271; called by muse, varscan2
- CSMD3 | c.1934A>G p.E645G (on ENST00000297405 / NM_001363185.1; = p.E541G on NM_052900.3) | Missense Mutation (SNP) | VAF 152/329 reads (46%) | SIFT tolerated (0.63); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- IGKV1-12 | c.152T>C p.I51T | Missense Mutation (SNP) | VAF 49/167 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.255); called by muse, mutect2, varscan2
- KIFC3 | c.1000T>C p.S334P | Missense Mutation (SNP) | VAF 5/71 reads (7%) | SIFT tolerated (0.11); PolyPhen benign (0.327); called by muse, mutect2
- MLLT1 | c.350_351insCAACCACCT p.N115_L117dup | In Frame Ins (INS) | VAF 64/148 reads (43%) | called by mutect2, varscan2
- NRDC | c.725A>T p.E242V | Missense Mutation (SNP) | VAF 224/448 reads (50%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.054); called by muse, varscan2
- HAS1 | c.765C>T p.D255= | Silent (SNP) | VAF 39/79 reads (49%) | catalogued as rs747392663; called by muse, mutect2, varscan2
- IDH2 | c.1185C>T p.A395= | Silent (SNP) | VAF 52/106 reads (49%) | called by muse, mutect2, varscan2
- SNX5 | c.496C>T p.L166= | Silent (SNP) | VAF 144/318 reads (45%) | called by muse, mutect2, varscan2
